Surgical pathology report (de-identified scan), TCGA case TCGA-KO-8409, project TCGA-KICH (Kidney Chromophobe), tissue source site MD Anderson Cancer Center, specimen TCGA-KO-8409-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL:

CHROMOPHOBE RENAL CELL CARCINOMA, EOSINOPHILIC TYPE, FUHRMAN'S
NUCLEAR GRADE 3.

TUMOR CONFINED TO THE KIDNEY.

TUMOR MEASURES 12.0 CM IN MAXIMUM DIMENSION.

Ureteral and vascular margins, free of tumor.

Adrenal gland, no tumor present.

(B) RETROPERITONEAL LYMPH NODE:

Lymph node with atypical follicular hyperplasia. (See comment)

COMMENT

The immunohistochemical studies are pending. An addendum report will be issued by Dr. , a hematopathologist, when these results become available.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL - A radical nephrectomy specimen and attached perinephric fat tissue (overall 26.0 x 13.0 x 8.0), including kidney (14.0 x 9.5 x 7.0 cm), unremarkable ureter (10.0 cm in length and 0.4 cm in diameter), adrenal gland(6.0 x 2.0 x 1.5 cm).

A well-defined, soft, mahogany brown tumor (12.0 x 8.5 x 7.0 cm) is located at the mid pole. A central scar is present. a central tan-yellow soft possibly necrotic focus measuring 1.5 x 1.0 cm is also identified. The tumor does not appear to involve the perirenal fat and sinus. The pelvis and ureter appear unremarkable.

The rest of the renal parenchyma appears unremarkable. An unremarkable adrenal gland is located superomedially.

INK CODE: Black - soft tissue margin.

SECTION CODE: A1, vascular and ureteral margin; A2, A3, sinus and tumor; A4, tumor and perinephric fat; A5, A6, central scar and necrosis; A7-A10, representative sections of tumor; A11, A12, tumor and normal kidney; A13, tumor; A14, normal kidney; A15, adrenal gland. RT/elk

(B) RETROPERITONEAL LYMPH NODE - A tan-yellow hemorrhagic matted lymph node measuring 12.3 x 3.0 x 1.5 cm. The specimen is serially sectioned and entirely submitted in B1-B20. [REDACTED]

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

[REDACTED]

Source: NCI Genomic Data Commons file 23367f48-5005-4157-8aaa-3694285450c9 (TCGA-KO-8409.DBAFAC56-9724-4EC3-9CBA-005EC26A645A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).